Somatic mutation profile of tumor specimen TARGET-40-PANVJJ-01A (aliquot TARGET-40-PANVJJ-01A-01Y) from TARGET case TARGET-40-PANVJJ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.8 years (5,044 days).
Specimen TARGET-40-PANVJJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed6a67ef-9481-4c93-aa39-b7d03e796266.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANVJJ-10A (Blood Derived Normal), aliquot TARGET-40-PANVJJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f68c6c76-40b2-472c-9fe5-ec1bed51ccaf

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Frame Shift Ins 8, Intron 4, Frame Shift Del 2, RNA 2, Silent 2, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 18/166 reads (11%) | catalogued as rs747299117; called by mutect2, varscan2
- DIAPH2 | c.2825A>T p.K942M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV61265994; called by muse, mutect2
- GPANK1 | c.800dup p.W268Lfs*12 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as rs765697080; called by mutect2, varscan2
- LHX4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs1274548296, COSV55375162; called by muse, mutect2, varscan2
- MAP3K9 | c.3016C>T p.P1006S (on ENST00000554752 / NM_001284230.1; = p.P1020S on NM_033141.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs778373003, COSV67122840; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | catalogued as rs777328830; called by mutect2, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 34/185 reads (18%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- NEB | c.12067C>A p.L4023I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as rs1048727898; called by muse, mutect2, varscan2
- NOTCH4 | c.5672dup p.G1892Rfs*24 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | catalogued as rs777647776; called by mutect2, varscan2
- OVGP1 | c.1054dup p.A352Gfs*10 | Frame Shift Ins (INS) | VAF 14/94 reads (15%) | catalogued as rs763064364; called by mutect2, varscan2
- OXGR1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs752266769; called by muse, mutect2, varscan2
- PLRG1 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104402231; called by mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 13/107 reads (12%) | catalogued as rs756557178; called by mutect2, varscan2
- THBS3 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs371452277; called by muse, mutect2, varscan2
- C1orf116 | c.1181C>A p.A394E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CENPL | c.455_458del p.R152Kfs*43 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- DNAH3 | c.1585-2A>T p.X529_splice | Splice Site (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.08); called by mutect2, varscan2
- GABRA4 | c.159C>G p.D53E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GASK1B | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by mutect2, varscan2
- KRTAP5-2 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NCKAP1L | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- PIGA | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- RAD54L2 | c.3617dup p.A1207Gfs*17 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- RIPOR2 | c.1337_1350del p.H446Pfs*17 | Frame Shift Del (DEL) | VAF 47/127 reads (37%) | called by mutect2, pindel, varscan2
- SLC6A14 | c.1231T>G p.L411V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF32 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.588); called by mutect2, varscan2
- PROM2 | c.105G>A p.P35= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs776099688, COSV58297197, COSV58299944; called by muse, mutect2, varscan2
- SLC17A8 | c.327A>T p.V109= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- AC053481.2 | n.135G>A | RNA (SNP) | VAF 8/20 reads (40%) | catalogued as rs558166184; called by muse, varscan2
- CZIB | c.147+17dup | Intron (INS) | VAF 8/40 reads (20%) | catalogued as rs765028518; called by pindel, varscan2
- LILRB1 | c.1800+159C>T | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as rs774574320; called by mutect2, varscan2
- MAP11 | c.*229dup | 3'UTR (INS) | VAF 33/159 reads (21%) | catalogued as rs1355654101; called by mutect2, varscan2
- OR2L6P | n.306T>G | RNA (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- RASA1 | c.2184+21C>T | Intron (SNP) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- SEMA6C | c.1714+38G>T | Intron (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- TIGD1 | c.*3385G>T | 3'UTR (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
